Somatic mutation profile of tumor specimen TARGET-20-PARKFB-03A (aliquot TARGET-20-PARKFB-03A-01D) from TARGET case TARGET-20-PARKFB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.2 years (6,631 days).
Specimen TARGET-20-PARKFB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c3b96aa-6d58-4be6-8e9d-8945c48f76fe.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARKFB-14A (Bone Marrow Normal), aliquot TARGET-20-PARKFB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b8c5a9c-2858-4365-befc-4e4f723213c6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 84/420 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4624A>T p.R1542* | Nonsense Mutation (SNP) | VAF 68/404 reads (17%) | called by muse, mutect2, varscan2
